Somatic mutation profile of tumor specimen CDDP-ACO6-TTP1-A (aliquot CDDP-ACO6-TTP1-A-1-0-D-A572-36) from CDDP_EAGLE case CDDP-ACO6, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65 years.
Specimen CDDP-ACO6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adda343d-663a-4d4e-b41d-e0042dcfcf2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-ACO6-NB1-A (Blood Derived Normal), aliquot CDDP-ACO6-NB1-A-1-0-D-A572-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/074c5577-9f19-4ffd-801a-2f538b77f640

The open-access MAF lists 2,052 somatic variants for this specimen: 1,447 protein-altering or splice-affecting, 395 silent, 210 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,244, Silent 395, Intron 90, Nonsense Mutation 85, Frame Shift Del 49, RNA 41, Splice Site 40, 3'UTR 27, 5'UTR 24, 5'Flank 19, Splice Region 17, 3'Flank 9.

Variants (750 of 2,052; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QB | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34813378, CM072911, COSV59246036; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F13A1 | c.1326C>A p.Y442* | Nonsense Mutation (SNP) | VAF 89/196 reads (45%) | catalogued as rs121913066, CM950379; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 65/98 reads (66%) | hotspot (GDC flag); catalogued as COSV52676020, COSV52700231, COSV52728094, COSV52766542; called by muse, mutect2, varscan2
- A1BG | c.770C>A p.T257N | Missense Mutation (SNP) | VAF 67/270 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV54049849; called by muse, mutect2, varscan2
- AADACL3 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs1188731444; called by muse, mutect2, varscan2
- ABCB4 | c.3634C>A p.L1212M (on ENST00000265723 / NM_018849.3; = p.L1205M on NM_000443.4) | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55937612; called by muse, varscan2
- ABCB5 | c.638C>A p.T213K | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV51721326; called by muse, mutect2, varscan2
- ABCD2 | c.890C>A p.S297* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs773549369; called by muse, mutect2, varscan2
- ABCD4 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.973); catalogued as rs1186487692, COSV53992722; called by mutect2, varscan2
- ACBD5 | c.1324C>T p.R442* (on ENST00000375888 / NM_001352568.1; = p.R433* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 58/129 reads (45%) | catalogued as rs1426447692, COSV65517815, COSV65520289; called by muse, mutect2, varscan2
- ACCS | c.556+1del | Frame Shift Del (DEL) | VAF 22/81 reads (27%) | catalogued as rs1207790264; called by pindel, varscan2*
- ACTL7B | c.68G>T p.R23L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101012549, COSV65927569; called by muse, mutect2, varscan2
- ADAM22 | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV55985746; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1337G>T p.C446F | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56477319; called by muse, mutect2, varscan2
- ADAMTS12 | c.4352C>T p.P1451L | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV61283758; called by muse, mutect2, varscan2
- ADCY8 | c.2121G>A p.M707I | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.437); catalogued as COSV53909565; called by muse, mutect2
- ADGB | c.3451C>A p.L1151I | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV62234673; called by muse, mutect2, varscan2
- ADGRA2 | c.1967G>T p.S656I | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.067); catalogued as COSV59446416; called by muse, mutect2
- ADGRV1 | c.8584T>A p.Y2862N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101315588; called by muse, varscan2
- ADNP | c.3069_3072del p.R1023Sfs*3 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as rs1279657093; called by mutect2, pindel, varscan2
- ADSS2 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63696582; called by muse, mutect2, varscan2
- ALMS1 | c.5800C>T p.P1934S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.172); catalogued as rs143859223, COSV100044093; called by muse, mutect2, varscan2
- AMD1 | c.640C>A p.P214T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs370680093; called by mutect2, varscan2
- AMER2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.875); catalogued as rs1398264895; called by muse, mutect2, varscan2
- AMTN | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV59488444; called by muse, mutect2, varscan2
- ANGPTL8 | c.438C>A p.Y146* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as rs749170186, COSV52949122; called by muse, mutect2, varscan2
- ANK2 | c.11477T>C p.I3826T | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs1312091704, COSV99053426; called by muse, mutect2, varscan2
- ANK3 | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.79); catalogued as rs1227944205; called by muse, mutect2, varscan2
- ANKRD30A | c.2827A>G p.T943A (on ENST00000611781; = p.T887A on NM_052997.2) | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1413227658, COSV64612550; called by muse, mutect2, varscan2
- ANO8 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs141211641; called by muse, mutect2
- ANO9 | c.1510C>T p.R504C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60382497; called by muse, mutect2, varscan2
- ANXA1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs752285742, COSV57412673; called by muse, mutect2, varscan2
- APOBEC1 | c.212C>A p.T71K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.592); catalogued as COSV57548468; called by muse, mutect2, varscan2
- AQP12A | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as rs533085451; called by muse, mutect2, varscan2
- ARHGAP31 | c.2449C>G p.L817V | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs541827684; called by muse, mutect2, varscan2
- ARPP21 | c.1460-1G>T p.X487_splice | Splice Site (SNP) | VAF 6/17 reads (35%) | catalogued as COSV51792148; called by mutect2, varscan2
- ASCC3 | c.6367G>T p.D2123Y | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV104427310; called by muse, mutect2, varscan2
- ASL | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs901715532, COSV100508968; called by muse, mutect2, varscan2
- ASTL | c.757C>A p.P253T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1213856101; called by muse, mutect2, varscan2
- ASXL3 | c.2338T>A p.S780T | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV52470396; called by muse, mutect2, varscan2
- ATP8B3 | c.719T>G p.V240G | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1233741061; called by muse, mutect2, varscan2
- B4GALNT4 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.18); catalogued as rs1316787870; called by muse, mutect2, varscan2
- BARD1 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53618838; called by muse, mutect2, varscan2
- BBS9 | c.2115+2T>G p.X705_splice (on ENST00000242067 / NM_001348036.1; = p.X665_splice on NM_014451.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 16/138 reads (12%) | catalogued as COSV99627690; called by muse, varscan2
- BIRC7 | c.863C>A p.P288H (on ENST00000217169 / NM_139317.3; = p.P270H on NM_022161.4) | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs199611858, COSV53900728; called by muse, mutect2, varscan2
- BMP6 | c.527C>A p.P176Q | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as rs745910275, COSV51670260; called by muse, mutect2, varscan2
- BRINP3 | c.2241G>T p.Q747H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV66526036, COSV99054908; called by muse, mutect2, varscan2
- BRINP3 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs1293567748; called by muse, varscan2
- BRINP3 | c.823del p.E275Kfs*32 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | catalogued as COSV66527745; called by pindel, varscan2
- C4orf50 | c.747G>C p.R249S (on ENST00000324058; = p.R1481S on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs752133391; called by muse, mutect2, varscan2
- C5orf47 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1029065220; called by muse, mutect2, varscan2
- C6orf118 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as rs765506488; called by muse, mutect2, varscan2
- C6orf118 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV57813770; called by muse, mutect2, varscan2
- CACNA1B | c.4072C>G p.L1358V | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1423450234; called by muse, mutect2, varscan2
- CACNA1S | c.4228G>T p.D1410Y | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100754873; called by muse, mutect2, varscan2
- CACNG3 | c.91G>T p.D31Y | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50086695; called by muse, mutect2, varscan2
- CAMK2G | c.1501G>A p.V501M (on ENST00000423381 / NM_001367518.1; = p.V438M on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.656); catalogued as rs1243870956, COSV55214280; called by muse, mutect2, varscan2
- CAPN5 | c.505G>A p.G169R (on ENST00000456580; = p.G129R on NM_004055.5) | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375949463, COSV99582626; called by muse, mutect2
- CCDC102A | c.356G>C p.R119P | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99265239; called by mutect2, varscan2
- CCDC149 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100164712; called by muse, mutect2, varscan2
- CCDC178 | c.2516C>A p.A839D (on ENST00000383096 / NM_001105528.3; = p.A801D on NM_198995.3) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as COSV55794609; called by muse, mutect2, varscan2
- CCDC198 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV53601646; called by muse, mutect2, varscan2
- CCSER1 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as COSV100391512; called by muse, mutect2, varscan2
- CCT8L2 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 42/193 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63462168; called by muse, mutect2, varscan2
- CDC42BPG | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61346148; called by muse, mutect2, varscan2
- CDH10 | c.2344G>T p.G782W | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100051106; called by muse, mutect2, varscan2
- CDH12 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66426603, COSV66435681; called by muse, mutect2, varscan2
- CDH9 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV50341599; called by muse, mutect2, varscan2
- CDK13 | c.2237del p.P746Qfs*22 | Frame Shift Del (DEL) | VAF 35/159 reads (22%) | catalogued as COSV51707099, COSV99475820; called by mutect2, pindel, varscan2
- CENPF | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100871609, COSV65276845; called by muse, mutect2, varscan2
- CHADL | c.270C>A p.H90Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as rs201876521; called by muse, mutect2, varscan2
- CHD8 | c.3952G>T p.E1318* (on ENST00000646647 / NM_001170629.2; = p.E1039* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as COSV63219661; called by muse, varscan2
- CHD9 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs763829620; called by muse, mutect2, varscan2
- CHIT1 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99705645; called by mutect2, varscan2
- CHORDC1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 45/296 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as COSV57706914; called by muse, mutect2, varscan2
- CLNK | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57014554; called by muse, mutect2, varscan2
- CLPB | c.1141G>T p.G381* | Nonsense Mutation (SNP) | VAF 43/131 reads (33%) | catalogued as COSV53628852; called by muse, mutect2, varscan2
- CLUH | c.1595G>T p.R532L (on ENST00000435359; = p.R570L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV70928766; called by muse, mutect2, varscan2
- CLVS1 | c.478C>G p.R160G | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57977822; called by muse, mutect2, varscan2
- CNGB3 | c.1969C>A p.P657T | Missense Mutation (SNP) | VAF 82/139 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as COSV60695409; called by muse, mutect2, varscan2
- CNTNAP4 | c.2341G>T p.G781W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255883298; called by muse, mutect2, varscan2
- COL11A1 | c.2232G>C p.K744N | Missense Mutation (SNP) | VAF 68/294 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs765354732; called by muse, mutect2, varscan2
- COL16A1 | c.603G>T p.R201S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs1452530018, COSV54702485; called by muse, mutect2, varscan2
- COL22A1 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV57327929; called by muse, mutect2, varscan2
- COL2A1 | c.342+1G>A p.X114_splice | Splice Site (SNP) | VAF 63/187 reads (34%) | catalogued as CS104510; called by muse, mutect2, varscan2
- COL5A1 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs751948105; called by muse, mutect2, varscan2
- COL9A2 | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101028331; called by muse, mutect2, varscan2
- COL9A3 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99069433; called by muse, mutect2
- COQ3 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758185659; called by mutect2, varscan2
- CPED1 | c.3004C>A p.H1002N | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs147434701, COSV100119948; called by muse, mutect2, varscan2
- CPNE1 | c.151C>G p.R51G (on ENST00000352393; = p.R56G on NM_003915.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs189152020; called by muse, mutect2, varscan2
- CRYBG2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as rs566879984, COSV57485241; called by mutect2, varscan2
- CSMD3 | c.9998C>T p.A3333V (on ENST00000297405 / NM_001363185.1; = p.A3164V on NM_052900.3) | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as rs1434662909; called by muse, mutect2, varscan2
- CSMD3 | c.5182G>C p.D1728H (on ENST00000297405 / NM_001363185.1; = p.D1624H on NM_052900.3) | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.905); catalogued as rs1449589129, COSV52247900; called by muse, mutect2
- CSN3 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.866); catalogued as rs200375927, COSV59245033; called by muse, mutect2, varscan2
- CSTF2T | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100484294; called by muse, mutect2, varscan2
- CTNNA3 | c.1582C>A p.Q528K | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV65590442; called by muse, mutect2, varscan2
- CYTH4 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.586); catalogued as COSV50631701; called by muse, mutect2, varscan2
- DCLK1 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55211431, COSV99711902; called by muse, mutect2, varscan2
- DDX50 | c.1815G>T p.W605C | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101007170; called by muse, mutect2, varscan2
- DENND1B | c.738C>G p.I246M | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470625374; called by muse, varscan2
- DENND5B | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV60901618; called by muse, mutect2, varscan2
- DERL1 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99418721; called by muse, mutect2, varscan2
- DGKB | c.2307+8C>T | Splice Region (SNP) | VAF 20/101 reads (20%) | catalogued as rs867753238, COSV51816159; called by muse, mutect2, varscan2
- DHCR7 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM154264, COSV100832167; called by muse, mutect2, varscan2
- DHTKD1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1413322402, COSV99536790; called by muse, mutect2, varscan2
- DKK1 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 19/217 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64760900; called by muse, mutect2
- DLGAP2 | c.281G>T p.C94F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1443075521; called by muse, mutect2, varscan2
- DMBT1 | c.943del p.H315Tfs*49 | Frame Shift Del (DEL) | VAF 46/126 reads (37%) | catalogued as rs1209453982, COSV57536645; called by mutect2, pindel, varscan2
- DMD | c.4027G>T p.E1343* | Nonsense Mutation (SNP) | VAF 56/111 reads (50%) | catalogued as COSV63776196; called by muse, mutect2, varscan2
- DNAH10 | c.2156G>A p.R719K (on ENST00000409039; = p.R658K on NM_207437.3) | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101292960; called by muse, mutect2
- DOCK2 | c.4583C>A p.S1528Y | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915544; called by muse, mutect2, varscan2
- DPT | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.201); catalogued as rs745685247; called by muse, mutect2, varscan2
- DPYSL5 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 133/287 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV56515958; called by muse, mutect2, varscan2
- DSP | c.1315G>A p.V439I | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.291); catalogued as rs587782941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYRK1A | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV100117401; called by muse, mutect2, varscan2
- EDN3 | c.478G>T p.A160S | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.023); catalogued as COSV61106928; called by muse, mutect2, varscan2
- EGR4 | c.1327G>T p.A443S (on ENST00000545030; = p.A340S on NM_001965.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs1472614080; called by muse, mutect2, varscan2
- ELN | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs750602142; called by muse, varscan2
- EML2 | c.819del p.N274Tfs*120 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | catalogued as rs1568457333; called by mutect2, pindel, varscan2
- ENTHD1 | c.1670G>T p.R557L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753644902, COSV57319440; called by muse, mutect2, varscan2
- EPB41L1 | c.786G>T p.R262S | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52436884, COSV52439470; called by muse, mutect2, varscan2
- EPHA2 | c.2669+1G>T p.X890_splice | Splice Site (SNP) | VAF 38/110 reads (35%) | catalogued as rs1299107532, COSV104422084; called by muse, mutect2, varscan2
- EPHA6 | c.2770G>C p.A924P (on ENST00000389672 / NM_001080448.3; = p.A316P on NM_173655.4) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67557843; called by muse, mutect2, varscan2
- EPN2 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs766973140, COSV59061306; called by muse, mutect2, varscan2
- ERBB4 | c.574T>C p.S192P | Missense Mutation (SNP) | VAF 75/271 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV53591164; called by muse, mutect2, varscan2
- ERICH3 | c.2713G>T p.A905S | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV58601773; called by muse, mutect2, varscan2
- ERICH3 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370760033; called by muse, mutect2
- ESRRB | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55062768; called by muse, mutect2, varscan2
- EVC | c.2689-2A>C p.X897_splice | Splice Site (SNP) | VAF 76/317 reads (24%) | catalogued as COSV99381735; called by muse, mutect2, varscan2
- EVX1 | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1033939449; called by muse, varscan2
- FAM117B | c.1022G>T p.R341L | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57419289; called by muse, mutect2, varscan2
- FAM120C | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV60259212, COSV60262491; called by muse, mutect2, varscan2
- FAM71A | c.646C>T p.Q216* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as COSV99674954; called by mutect2, varscan2
- FAT2 | c.7069C>T p.P2357S | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV99942904; called by muse, mutect2, varscan2
- FCHO1 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.777); catalogued as rs1167242669; called by muse, mutect2
- FCRL5 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62512252; called by muse, mutect2, varscan2
- FER1L6 | c.1106G>T p.G369V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446524053; called by muse, mutect2, varscan2
- FGGY | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99054555; called by muse, mutect2, varscan2
- FLG | c.7502C>A p.S2501Y | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV64244638; called by muse, mutect2, varscan2
- FRAS1 | c.8323G>A p.D2775N | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as COSV53588520; called by muse, mutect2, varscan2
- FSCN3 | c.1403T>C p.L468P | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as rs374297879; called by muse, mutect2, varscan2
- FSIP1 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100617938; called by muse, mutect2, varscan2
- GAK | c.1885G>T p.V629L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.088); catalogued as rs183655284; called by muse, mutect2, varscan2
- GANC | c.2544G>T p.Q848H | Missense Mutation (SNP) | VAF 35/80 reads (44%) | PolyPhen benign (0); catalogued as COSV58808767; called by muse, mutect2, varscan2
- GAP43 | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59344305; called by muse, mutect2, varscan2
- GATA6 | c.1767G>T p.W589C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52526927; called by muse, mutect2, varscan2
- GCN1 | c.5406G>T p.Q1802H | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392522973; called by muse, mutect2, varscan2
- GJA5 | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV54785078; called by muse, mutect2, varscan2
- GLDC | c.1455G>T p.L485F | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.125); catalogued as rs1406438579; called by muse, mutect2, varscan2
- GLYATL1 | c.455G>A p.W152* (on ENST00000317391 / NM_001354699.1; = p.W183* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV55607364; called by muse, mutect2, varscan2
- GOLGA2 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV70168111; called by muse, mutect2, varscan2
- GOLGA8T | c.1441C>A p.H481N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV68681733; called by muse, mutect2, varscan2
- GPR158 | c.351C>A p.S117R | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as COSV66284761; called by muse, mutect2, varscan2
- GPR83 | c.410G>T p.W137L | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.9); catalogued as COSV54717461; called by muse, mutect2, varscan2
- GPR84 | c.875C>G p.P292R | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV57210560; called by muse, mutect2, varscan2
- GPR84 | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.142); catalogued as COSV57209324; called by muse, mutect2, varscan2
- GPRIN3 | c.1310A>T p.D437V | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs1331641630; called by muse, mutect2, varscan2
- GRIN3A | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 63/380 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.586); catalogued as rs1197684843; called by muse, mutect2, varscan2
- GRIP2 | c.820G>T p.V274F (on ENST00000619221; = p.V177F on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333624401; called by muse, mutect2, varscan2
- GRTP1 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV58150790; called by muse, mutect2, varscan2
- H3C2 | c.191G>C p.R64P | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.169); catalogued as COSV52517991; called by muse, mutect2, varscan2
- HCN1 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV57495408; called by muse, mutect2, varscan2
- HELZ | c.2990G>T p.R997L | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62376398; called by muse, mutect2, varscan2
- HPCAL1 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100323844; called by muse, mutect2, varscan2
- HPSE2 | c.615G>T p.R205S | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); catalogued as COSV65191970; called by muse, mutect2
- HRNR | c.8441A>G p.K2814R | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs752126891; called by muse, varscan2
- HS3ST4 | c.961C>A p.L321I | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV58811055; called by muse, mutect2, varscan2
- HSPA12A | c.356G>T p.R119M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100979950; called by muse, mutect2, varscan2
- HSPB6 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 123/188 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750533067, COSV50000617; called by muse, mutect2, varscan2
- HTRA1 | c.714C>A p.Y238* | Nonsense Mutation (SNP) | VAF 34/279 reads (12%) | catalogued as COSV64563618; called by muse, mutect2, varscan2
- HYDIN | c.13178C>A p.P4393H | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.855); catalogued as COSV66641463; called by muse, mutect2, varscan2
- HYDIN | c.1147C>T p.R383* | Nonsense Mutation (SNP) | VAF 27/126 reads (21%) | catalogued as rs543553606, COSV55496566, COSV99863380; called by muse, mutect2, varscan2
- IL2RB | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 93/145 reads (64%) | catalogued as COSV53427436; called by muse, mutect2, varscan2
- IL2RG | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 81/117 reads (69%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV52148799; called by muse, mutect2, varscan2
- IL36G | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1201041305; called by muse, mutect2, varscan2
- IL7R | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.28); catalogued as COSV57407721, COSV57415389; called by muse, mutect2, varscan2
- INAVA | c.1194G>T p.R398S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs775507031; called by mutect2, varscan2
- IPCEF1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as rs761913720, COSV54552096; called by mutect2, varscan2
- IRAG2 | c.3236G>A p.G1079E (on ENST00000636465; = p.G124E on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as COSV63137595; called by muse, mutect2
- IRF8 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 26/180 reads (14%) | catalogued as COSV99236193; called by muse, mutect2, varscan2
- IRS1 | c.3032G>T p.S1011I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV100525086; called by muse, mutect2, varscan2
- ISOC2 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375030964, COSV50035011; called by muse, varscan2
- ITGA11 | c.2789G>C p.G930A | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as COSV59879367; called by muse, mutect2, varscan2
- ITGA4 | c.637A>T p.M213L | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1184289724; called by muse, mutect2, varscan2
- ITGB6 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs978656099; called by muse, mutect2, varscan2
- JSRP1 | c.692C>A p.A231E | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.721); catalogued as rs1447612516; called by muse, mutect2, varscan2
- KANSL1 | c.2989C>T p.H997Y (on ENST00000574590 / NM_001193465.2; = p.H998Y on NM_015443.4) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.206); catalogued as rs1286786826; called by muse, mutect2, varscan2
- KCNA1 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 60/111 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as COSV66836423, COSV66837186; called by muse, mutect2, varscan2
- KCNA5 | c.1736G>A p.G579D | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as rs753546444; called by muse, mutect2, varscan2
- KCND2 | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV58596346; called by muse, mutect2, varscan2
- KCNK15 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.435); catalogued as rs6073539; called by muse, mutect2, varscan2
- KCNK18 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs767366005; called by muse, mutect2, varscan2
- KCNN2 | c.65G>C p.R22P (on ENST00000264773; = p.R234P on NM_021614.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.952); catalogued as rs139352881; called by muse, mutect2
- KCNQ5 | c.2136A>T p.Q712H | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59648510; called by muse, mutect2, varscan2
- KEL | c.659C>A p.T220K | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV62334972; called by muse, mutect2, varscan2
- KHDC3L | c.172C>A p.R58= | Splice Region (SNP) | VAF 20/85 reads (24%) | catalogued as COSV64869193; called by muse, varscan2
- KIF17 | c.2945C>A p.P982Q | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs1248691105; called by muse, mutect2, varscan2
- KIF21A | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765481237; called by muse, mutect2, varscan2
- KLHL1 | c.568C>A p.Q190K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.109); catalogued as COSV64783534; called by muse, mutect2, varscan2
- KLHL29 | c.1662C>A p.N554K | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV99942963; called by muse, mutect2, varscan2
- KMT2C | c.9283C>T p.P3095S | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208081081, COSV104383872; called by muse, mutect2, varscan2
- KMT2D | c.6890C>T p.P2297L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as rs778904794, COSV56409342; called by muse, mutect2, varscan2
- KRTAP13-1 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT tolerated (0.38); PolyPhen benign (0.062); catalogued as COSV100819897, COSV62663095; called by muse, mutect2, varscan2
- L1CAM | c.1268-1G>T p.X423_splice | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as CS099758; called by muse, mutect2, varscan2
- LAD1 | c.24G>T p.W8C | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66213282; called by muse, mutect2, varscan2
- LCK | c.731C>A p.T244K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs778448252; called by muse, mutect2, varscan2
- LCMT1 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 34/128 reads (27%) | catalogued as rs752895115; called by muse, mutect2, varscan2
- LDB2 | c.900G>C p.M300I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV58770835; called by muse, mutect2
- LGR5 | c.385G>T p.V129L | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.207); catalogued as COSV57009397; called by mutect2, varscan2
- LHCGR | c.1214A>T p.D405V | Missense Mutation (SNP) | VAF 125/223 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1328076298; called by muse, mutect2, varscan2
- LHX5 | c.1019G>T p.R340M | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.847); catalogued as COSV55663555; called by muse, mutect2, varscan2
- LILRB5 | c.1375G>T p.G459W (on ENST00000449561 / NM_001081442.3; = p.G458W on NM_006840.5) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV100300194; called by muse, mutect2, varscan2
- LIN28A | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 81/386 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs748777822, COSV99575226; called by muse, varscan2
- LIPN | c.817C>G p.Q273E | Missense Mutation (SNP) | VAF 46/74 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV68383640; called by muse, mutect2, varscan2
- LMTK2 | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs752539999; called by muse, mutect2, varscan2
- LRFN5 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53243582; called by muse, mutect2, varscan2
- LRRC55 | c.160C>G p.Q54E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV73006389; called by muse, mutect2, varscan2
- LRRC75A | c.957G>C p.E319D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs542961813; called by mutect2, varscan2
- LRRK1 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV52623413; called by muse, mutect2
- LRRTM1 | c.535C>A p.R179S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99702898; called by muse, mutect2, varscan2
- LRRTM3 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV63672298; called by muse, mutect2, varscan2
- LSMEM1 | c.196G>T p.G66W | Missense Mutation (SNP) | VAF 66/278 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57196848; called by mutect2, varscan2
- LTBP1 | c.5015G>T p.R1672L (on ENST00000404816 / NM_206943.4; = p.R1346L on NM_000627.4) | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs145029619; called by muse, mutect2, varscan2
- MAGEB6 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV66872769; called by muse, mutect2, varscan2
- MAGEC1 | c.1189C>G p.H397D | Missense Mutation (SNP) | VAF 51/75 reads (68%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs769507677, COSV53581939; called by muse, mutect2, varscan2
- MAP3K4 | c.2375G>T p.R792M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100815029; called by muse, mutect2, varscan2
- MAPK4 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs755657525; called by muse, mutect2, varscan2
- MELTF | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs11541814; called by muse, mutect2, varscan2
- METTL18 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1314311105; called by muse, mutect2, varscan2
- MFSD8 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV99614397; called by muse, mutect2, varscan2
- MMEL1 | c.597del p.W199Cfs*12 | Frame Shift Del (DEL) | VAF 48/132 reads (36%) | catalogued as COSV56519183; called by mutect2, pindel*, varscan2
- MMP2 | c.1219C>A p.H407N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54602347; called by muse, mutect2, varscan2
- MMP9 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761471689; called by muse, mutect2
- MORC1 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99225631; called by muse, mutect2, varscan2
- MRPL38 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); catalogued as rs1314066200; called by muse, mutect2, varscan2
- MTMR1 | c.260G>T p.R87M | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99059531; called by muse, mutect2, varscan2
- MUC17 | c.13189del p.A4397Qfs*5 | Frame Shift Del (DEL) | VAF 34/140 reads (24%) | catalogued as COSV60291185, COSV60300279; called by mutect2*, pindel, varscan2*
- MUC19 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); catalogued as rs1464755131; called by muse, mutect2, varscan2
- MUC4 | c.7465G>C p.V2489L | Missense Mutation (SNP) | VAF 28/545 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.101); catalogued as rs1365508574; called by muse, mutect2
- MYH6 | c.5806C>A p.H1936N | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59305830; called by muse, mutect2, varscan2
- MYO15A | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); catalogued as rs1206025615; called by muse, mutect2, varscan2
- MYO3A | c.3095C>A p.A1032D | Missense Mutation (SNP) | VAF 52/327 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV56346346; called by mutect2, varscan2
- MYOCD | c.1795C>A p.P599T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1392561541, COSV58502815; called by muse, mutect2, varscan2
- NALCN | c.1712G>T p.W571L | Missense Mutation (SNP) | VAF 49/77 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99213625; called by muse, mutect2, varscan2
- NAT8 | c.139C>G p.L47V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV55542274; called by muse, mutect2, varscan2
- NBR1 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.02); catalogued as COSV57833696; called by muse, mutect2, varscan2
- NCF1 | c.237G>T p.K79N | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.396); catalogued as COSV56875451; called by muse, mutect2, varscan2
- NCR1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as COSV52555784; called by muse, mutect2, varscan2
- NDST3 | c.2305G>T p.G769W | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56619072, COSV99630267; called by muse, mutect2, varscan2
- NEXMIF | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs1284374791; called by muse, mutect2, varscan2
- NFRKB | c.1835C>T p.P612L (on ENST00000446488 / NM_001143835.2; = p.P637L on NM_006165.3) | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1378322928; called by muse, mutect2, varscan2
- NLGN1 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs61755041, COSV100849079; called by muse, mutect2, varscan2
- NLRC4 | c.2896C>A p.Q966K | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV50875226; called by muse, mutect2, varscan2
- NLRP11 | c.1734G>C p.M578I | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1373437786, COSV100789855, COSV64086371; called by muse, mutect2, varscan2
- NLRP3 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV60223058; called by muse, varscan2
- NOMO1 | c.966C>T p.P322= | Splice Region (SNP) | VAF 39/198 reads (20%) | catalogued as rs759013617; called by muse, mutect2, varscan2
- NPIPB15 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.583); catalogued as rs771635253, COSV70436463; called by muse, mutect2, varscan2
- NPR1 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303075641; called by muse, mutect2, varscan2
- NPTXR | c.824A>G p.Q275R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.714); catalogued as rs779666889; called by mutect2, varscan2
- NT5C3A | c.269G>C p.R90T (on ENST00000610140 / NM_001374335.1; = p.R56T on NM_016489.13) | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as COSV54239651; called by muse, mutect2, varscan2
- OLFM3 | c.574G>T p.G192C (on ENST00000338858 / NM_001288821.1; = p.G172C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58805206; called by muse, varscan2
- OR10A4 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV65841696, COSV65841802; called by muse, mutect2, varscan2
- OR10J1 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs368823977; called by muse, mutect2, varscan2
- OR10K2 | c.787C>A p.Q263K | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59220915; called by muse, mutect2, varscan2
- OR2AJ1 | c.386C>G p.P129R | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59089383; called by muse, mutect2, varscan2
- OR2F1 | c.166C>A p.H56N | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV101231299, COSV67332134; called by muse, mutect2, varscan2
- OR2G2 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV60740011; called by muse, mutect2, varscan2
- OR2M5 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100822868; called by muse, mutect2, varscan2
- OR2T1 | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV63542758; called by muse, mutect2, varscan2
- OR4D10 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs773272297, COSV73259969; called by muse, mutect2, varscan2
- OR4N2 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 21/207 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs772398252; called by muse, mutect2, varscan2
- OR51Q1 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773544910, COSV56180113; called by muse, mutect2, varscan2
- OR51Q1 | c.242C>A p.P81H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV56177805; called by muse, mutect2, varscan2
- OR51S1 | c.392C>A p.A131E | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV59058102; called by muse, mutect2, varscan2
- OR5H1 | c.284C>A p.S95Y | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.046); catalogued as COSV63403619; called by muse, mutect2, varscan2
- OR5J2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56621263; called by muse, mutect2
- OR6K3 | c.856G>A p.D286N (on ENST00000368146; = p.D270N on NM_001005327.2) | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.654); catalogued as COSV100933866; called by muse, mutect2, varscan2
- OR6K6 | c.397C>A p.H133N (on ENST00000368144; = p.H109N on NM_001005184.1) | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100933662; called by muse, mutect2, varscan2
- OR6K6 | c.596C>A p.S199Y (on ENST00000368144; = p.S175Y on NM_001005184.1) | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as rs760148925; called by muse, mutect2, varscan2
- OR8B2 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100899409; called by muse, mutect2, varscan2
- OR9A4 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 56/121 reads (46%) | catalogued as COSV71884947; called by muse, mutect2, varscan2
- OTOF | c.2959G>A p.V987I (on ENST00000272371 / NM_194248.3; = p.V240I on NM_004802.4) | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs772973509, COSV55523019; called by muse, mutect2, varscan2
- OTOP3 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100173174; called by mutect2, varscan2
- OTX2 | c.30C>A p.Y10* | Nonsense Mutation (SNP) | VAF 22/166 reads (13%) | catalogued as COSV99044938; called by muse, mutect2, varscan2
- P2RY8 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 97/147 reads (66%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV67177190; called by muse, mutect2, varscan2
- PAPPA2 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs200511037; called by mutect2, varscan2
- PCDH15 | c.5624C>A p.P1875H | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); catalogued as COSV57371502; called by muse, varscan2
- PCDH9 | c.3306G>T p.R1102S (on ENST00000377865 / NM_203487.3; = p.R1068S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as rs1314338545; called by muse, mutect2, varscan2
- PCDHA13 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as rs1258227427; called by muse, mutect2, varscan2
- PCDHB6 | c.2142G>T p.R714S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV50745907; called by muse, mutect2, varscan2
- PCDHB8 | c.1699C>G p.Q567E | Missense Mutation (SNP) | VAF 142/386 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as COSV50823875; called by muse, mutect2, varscan2
- PCDHGA6 | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.025); catalogued as rs748933501, COSV53893353; called by muse, mutect2, varscan2
- PCDHGA6 | c.1940A>G p.Q647R | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.029); catalogued as rs1299988468; called by muse, mutect2, varscan2
- PCK1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60131629; called by muse, mutect2, varscan2
- PCNX3 | c.2707G>A p.V903M | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV63134911; called by muse, mutect2, varscan2
- PDE7B | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs868388213, COSV57497954; called by muse, mutect2, varscan2
- PDHA2 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99757342; called by muse, mutect2, varscan2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, mutect2, varscan2
- PHOX2B | c.653C>G p.P218R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV56930570; called by muse, varscan2
- PIGR | c.1513G>T p.A505S | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.186); catalogued as COSV62903261; called by muse, mutect2, varscan2
- PIP5K1A | c.1570G>T p.E524* (on ENST00000368888 / NM_001135638.2; = p.E511* on NM_003557.3) | Nonsense Mutation (SNP) | VAF 30/213 reads (14%) | catalogued as COSV62957740; called by muse, mutect2, varscan2
- PKD1L2 | c.2323G>T p.V775L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as rs954154571; called by muse, mutect2, varscan2
- PKHD1L1 | c.4333C>A p.P1445T | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV101006745; called by muse, mutect2, varscan2
- PLCG2 | c.334G>T p.A112S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV63872398; called by muse, mutect2
- PLCH2 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 20/82 reads (24%) | catalogued as rs34753700; called by muse, mutect2, varscan2
- PLEKHG5 | c.927G>C p.Q309H (on ENST00000400915 / NM_001042663.3; = p.Q272H on NM_020631.6) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV61701633; called by muse, mutect2, varscan2
- PLEKHO2 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV60262673; called by muse, mutect2, varscan2
- PNLDC1 | c.642G>T p.W214C | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.947); catalogued as COSV51705467; called by muse, mutect2, varscan2
- POLG | c.2087A>C p.Y696S | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99175064; called by muse, mutect2
- POM121L2 | c.2627C>A p.A876D | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1561789903; called by muse, mutect2, varscan2
- PRAMEF12 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.382); catalogued as COSV63214962; called by muse, mutect2, varscan2
- PRDM13 | c.1054C>A p.H352N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.057); catalogued as COSV65030154; called by muse, varscan2
- PRDM14 | c.945A>G p.I315M | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1186100079; called by muse, mutect2, varscan2
- PRKACA | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58066995; called by muse, mutect2, varscan2
- PRKDC | c.10630G>T p.D3544Y | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs189595774; called by muse, mutect2, varscan2
- PRMT8 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1275728854; called by muse, mutect2, varscan2
- PROM2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs1161628972, COSV58297664; called by muse, mutect2, varscan2
- PRPF8 | c.2621C>T p.P874L | Missense Mutation (SNP) | VAF 156/231 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043396; called by muse, mutect2, varscan2
- PRR19 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as rs762950594; called by muse, mutect2, varscan2
- PRR27 | c.566C>A p.A189D | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.225); catalogued as rs1000902576; called by muse, mutect2, varscan2
- PRUNE2 | c.3311C>A p.S1104Y | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV65042778; called by muse, mutect2, varscan2
- PTCHD4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV59787657; called by muse, mutect2, varscan2
- PTPRB | c.5926C>A p.P1976T | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV54253422; called by muse, mutect2, varscan2
- PTPRB | c.4979G>A p.R1660H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.127); catalogued as rs778052516, COSV54244676, COSV99716272; called by muse, mutect2, varscan2
- PTPRD | c.3530G>C p.R1177P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61927867, COSV61939245; called by muse, mutect2, varscan2
- PTPRD | c.3529C>G p.R1177G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV61932307; called by muse, mutect2, varscan2
- PTPRH | c.1805G>A p.W602* | Nonsense Mutation (SNP) | VAF 36/136 reads (26%) | catalogued as rs377501245; called by muse, mutect2, varscan2
- PTPRO | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV55520030; called by muse, mutect2, varscan2
- PTPRT | c.2208G>T p.E736D | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.997); catalogued as rs1218906688; called by muse, mutect2, varscan2
- PTPRT | c.1688C>A p.S563Y | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.845); catalogued as COSV61983987; called by muse, varscan2
- PTPRT | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.158); catalogued as COSV62019827; called by muse, mutect2, varscan2
- PTTG1 | c.450C>G p.D150E | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.017); catalogued as rs1802499; called by muse, mutect2, varscan2
- RAP1GAP2 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370929572; called by muse, mutect2, varscan2
- RASSF6 | c.703G>T p.V235F (on ENST00000342081 / NM_201431.2; = p.V203F on NM_177532.5) | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs745667189; called by muse, mutect2, varscan2
- RBM20 | c.1245C>A p.S415R | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV65704013; called by muse, mutect2
- RDH10 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV53584356; called by muse, mutect2, varscan2
- RETREG3 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.84); catalogued as rs112002966; called by muse, varscan2
- RGS7BP | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV61836055; called by muse, mutect2, varscan2
- RIMS2 | c.2576C>T p.S859L (on ENST00000666250 / NM_001348490.2; = p.S667L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99198583; called by muse, mutect2, varscan2
- RNF180 | c.1040A>G p.D347G | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs112729405; called by muse, mutect2, varscan2
- ROBO3 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776865762; called by muse, mutect2, varscan2
- RP1L1 | c.6238C>A p.P2080T | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs755190750; called by muse, varscan2
- RPGRIP1 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as COSV52845571; called by muse, mutect2, varscan2
- RPS15 | c.175C>G p.R59G | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as rs747355862; called by muse, mutect2, varscan2
- RRP12 | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 45/231 reads (19%) | catalogued as rs762556732, COSV59671775; called by muse, mutect2, varscan2
- RSRC2 | c.208G>T p.G70* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as COSV59207327; called by muse, mutect2, varscan2
- RTL9 | c.4138C>T p.H1380Y | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.291); catalogued as rs1420371802; called by muse, mutect2, varscan2
- RYR1 | c.7076G>A p.R2359Q | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1387126664, CM140866, COSV62091679, COSV62112838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.13288G>T p.G4430W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as rs1192218827; called by muse, mutect2, varscan2
- RYR2 | c.6343G>T p.D2115Y | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63682803; called by muse, mutect2, varscan2
- RYR2 | c.12759G>C p.L4253F | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV63684386; called by muse, varscan2
- SAMD9L | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100560365; called by muse, mutect2, varscan2
- SART1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as COSV56711923; called by muse, mutect2, varscan2
- SCARA3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs199959277; called by muse, mutect2, varscan2
- SCN10A | c.2052G>T p.M684I | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV71862637; called by muse, mutect2, varscan2
- SDK1 | c.4876G>C p.G1626R | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.527); catalogued as COSV67355893; called by muse, mutect2, varscan2
- SEL1L3 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV53541646; called by mutect2, varscan2
- SERPINB7 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.541); catalogued as COSV100320860; called by muse, mutect2, varscan2
- SGMS1 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99052671; called by muse, mutect2, varscan2
- SH3RF2 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 40/173 reads (23%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.97); catalogued as rs753961992; called by muse, mutect2, varscan2
- SIDT1 | c.504C>A p.H168Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV53504220; called by muse, mutect2
- SIDT2 | c.2228G>C p.R743T | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV54054985; called by muse, varscan2
- SKOR2 | c.1330G>A p.A444T | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.691); catalogued as COSV68550665; called by muse, mutect2, varscan2
- SLC13A4 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1421497564; called by muse, mutect2, varscan2
- SLC15A4 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57163807; called by muse, mutect2, varscan2
- SLC20A1 | c.1618G>T p.G540W | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55613659; called by muse, mutect2
- SLC26A7 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 48/158 reads (30%) | catalogued as COSV52600525; called by muse, mutect2, varscan2
- SLC35F3 | c.285C>A p.D95E (on ENST00000366617 / NM_001300845.1; = p.D164E on NM_173508.4) | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.736); catalogued as COSV64020547; called by muse, mutect2, varscan2
- SLC35F5 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1259863213; called by muse, mutect2, varscan2
- SLC39A12 | c.1829C>A p.S610Y (on ENST00000377369 / NM_001145195.2; = p.S573Y on NM_152725.3) | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV66203153; called by muse, mutect2, varscan2
- SLC39A5 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV57190488, COSV57190530; called by muse, mutect2, varscan2
- SLC44A4 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs752284502; called by muse, mutect2, varscan2
- SLC45A3 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65655833; called by muse, mutect2, varscan2
- SLC4A4 | c.2843G>T p.R948L (on ENST00000264485 / NM_001098484.3; = p.R904L on NM_003759.4) | Missense Mutation (SNP) | VAF 66/187 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761021368; called by muse, mutect2, varscan2
- SLC6A15 | c.991C>G p.H331D | Missense Mutation (SNP) | VAF 69/263 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99880368; called by muse, mutect2, varscan2
- SLC7A4 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 84/475 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs780478475, COSV60383796; called by muse, mutect2, varscan2
- SLC8A1 | c.1364C>G p.S455C | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60471917; called by muse, mutect2, varscan2
- SLCO1B1 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV99917996; called by muse, mutect2, varscan2
- SLCO1B1 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV57009624; called by muse, mutect2, varscan2
- SMO | c.1192C>T p.R398* | Nonsense Mutation (SNP) | VAF 22/187 reads (12%) | catalogued as rs1199769385, COSV50829659, COSV50852373; called by muse, mutect2, varscan2
- SNAPC4 | c.4387C>T p.R1463W | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1196837339, COSV53730781, COSV53738463; called by muse, mutect2, varscan2
- SNX13 | c.683G>T p.C228F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.61); catalogued as rs769111402; called by mutect2, varscan2
- SP7 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58192154; called by muse, mutect2, varscan2
- SPATA31D1 | c.3794G>A p.R1265H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs376145655; called by muse, mutect2, varscan2
- SPRR2D | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs926691400; called by muse, mutect2, varscan2
- SQOR | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 70/225 reads (31%) | catalogued as rs1259720065; called by muse, mutect2, varscan2
- SRGAP3 | c.2473C>A p.L825M | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.969); catalogued as COSV100841482; called by muse, mutect2, varscan2
- SRP68 | c.1258C>T p.R420W | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs200440391, COSV57162879; called by muse, mutect2, varscan2
- SSBP3 | c.186G>T p.W62C | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62575050; called by muse, varscan2
- STAB2 | c.4468A>G p.R1490G | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs1285798966; called by muse, mutect2, varscan2
- STAC | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.445); catalogued as COSV56211062; called by muse, mutect2, varscan2
- STARD9 | c.553G>T p.V185L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs926747964; called by muse, mutect2, varscan2
- SUFU | c.552G>C p.Q184H | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV64016433; called by muse, mutect2, varscan2
- SUPT5H | c.2451G>T p.Q817H | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.036); catalogued as COSV100782045; called by muse, mutect2, varscan2
- SVEP1 | c.7054G>T p.G2352W | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52842297, COSV99929919; called by muse, mutect2, varscan2
- SYT14 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs758291845, COSV55048846, COSV55054244; called by muse, mutect2, varscan2
- TAF1A | c.328C>A p.H110N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV100601166; called by muse, mutect2, varscan2
- TASOR2 | c.6820C>G p.Q2274E | Missense Mutation (SNP) | VAF 75/168 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1465060038; called by muse, mutect2, varscan2
- TBC1D32 | c.3278G>T p.R1093M | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.893); catalogued as COSV99249399; called by muse, mutect2, varscan2
- TEAD1 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as COSV57566225; called by muse, mutect2, varscan2
- TENM2 | c.2302C>G p.R768G (on ENST00000518659 / NM_001122679.2; = p.R536G on NM_001080428.3) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV69134914; called by muse, mutect2, varscan2
- TIAM2 | c.1304C>G p.S435C | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV59706809; called by muse, varscan2
- TJP2 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55270291; called by muse, mutect2, varscan2
- TLL2 | c.2626G>T p.V876L | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV63573820; called by muse, mutect2, varscan2
- TMC6 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs746046230; called by muse, varscan2
- TMEM131 | c.1386C>G p.F462L | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs757424255; called by muse, mutect2, varscan2
- TMEM151B | c.1482C>G p.S494R | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs930747143; called by muse, mutect2, varscan2
- TMEM81 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.979); catalogued as COSV52705575; called by muse, mutect2, varscan2
- TRAF2 | c.1139-1G>T p.X380_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56038875; called by muse, mutect2
- TRAPPC9 | c.3094G>T p.V1032L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV66909501; called by mutect2, varscan2
- TRIM64B | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 74/300 reads (25%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.736); catalogued as rs538009586; called by muse, varscan2
- TRIM64B | c.195C>G p.N65K | Missense Mutation (SNP) | VAF 154/540 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61693629; called by muse, varscan2
- TRIOBP | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 76/676 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.088); catalogued as rs367774773; called by muse, varscan2
- TRPM8 | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as rs200547297, COSV61222741, COSV61224767; called by muse, mutect2, varscan2
- TTN | c.92656G>T p.G30886C (on ENST00000591111; = p.G23462C on NM_003319.4) | Missense Mutation (SNP) | VAF 34/177 reads (19%) | PolyPhen probably damaging (1); catalogued as COSV59997755; called by muse, mutect2, varscan2
- TTN | c.37928G>A p.R12643H (on ENST00000591111; = p.R5219H on NM_003319.4) | Missense Mutation (SNP) | VAF 89/295 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs368572799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.33190G>T p.E11064* (on ENST00000591111; = p.E10137* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 62/199 reads (31%) | catalogued as COSV60286822; called by muse, mutect2, varscan2
- TYRP1 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.769); catalogued as COSV104429659, COSV66357914, COSV66358419; called by muse, mutect2, varscan2
- UBASH3B | c.841A>G p.I281V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.251); catalogued as COSV52502555; called by muse, mutect2, varscan2
- UBXN2A | c.331G>T p.V111L | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.182); catalogued as rs1197413310; called by muse, mutect2, varscan2
- UGT2B10 | c.665G>A p.W222* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as rs779971456, COSV99607708; called by muse, mutect2, varscan2
- ULBP1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV57663715; called by mutect2, varscan2
- UNC5B | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1013739369, COSV58974440; called by muse, mutect2, varscan2
- UNC5D | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1452726121; called by muse, mutect2, varscan2
- UNK | c.742del p.R248Gfs*72 | Frame Shift Del (DEL) | VAF 30/93 reads (32%) | catalogued as COSV53141729; called by mutect2, pindel, varscan2
- USH2A | c.3533C>A p.P1178H | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56375447; called by muse, mutect2, varscan2
- USP13 | c.2548A>G p.K850E | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55865825; called by muse, mutect2, varscan2
- UXS1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 32/304 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51682978; called by muse, mutect2, varscan2
- VENTX | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100384149; called by muse, mutect2, varscan2
- VPS13B | c.9683G>A p.C3228Y | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs747611342; called by muse, mutect2, varscan2
- WDR26 | c.1255C>T p.H419Y (on ENST00000414423 / NM_001379403.1; = p.H319Y on NM_025160.7) | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419548298, COSV54355137; called by muse, mutect2, varscan2
- WDR64 | c.1621G>T p.G541W | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781006946, COSV63798627; called by muse, mutect2, varscan2
- XIRP2 | c.3394G>T p.G1132C (on ENST00000628543; = p.G1307C on NM_152381.6) | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740599; called by muse, mutect2, varscan2
- XIRP2 | c.3395G>T p.G1132V (on ENST00000628543; = p.G1307V on NM_152381.6) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99743965; called by muse, mutect2, varscan2
- XIRP2 | c.6983C>A p.T2328K (on ENST00000628543; = p.T2503K on NM_152381.6) | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs767329718; called by muse, mutect2, varscan2
- XKR6 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs777409714, COSV100440176; called by muse, mutect2, varscan2
- ZC3H18 | c.2824A>T p.I942F | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56326084; called by muse, varscan2
- ZFHX4 | c.3124C>A p.P1042T | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.033); catalogued as COSV51497439; called by muse, mutect2, varscan2
- ZFPM2 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV65873388; called by muse, mutect2
- ZFPM2 | c.2759G>T p.G920V | Missense Mutation (SNP) | VAF 333/448 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV101023698; called by muse, mutect2, varscan2
- ZIC1 | c.832C>A p.R278S | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99291824; called by muse, varscan2
- ZNF384 | c.1321G>T p.A441S (on ENST00000361959; = p.A380S on NM_133476.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.815); catalogued as rs759742610; called by muse, mutect2, varscan2
- ZNF395 | c.1438C>T p.R480* | Nonsense Mutation (SNP) | VAF 8/81 reads (10%) | catalogued as rs1336625843, COSV60429135, COSV60429732; called by mutect2, varscan2
- ZNF513 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs771161261; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF711 | c.915C>A p.I305= | Splice Region (SNP) | VAF 38/105 reads (36%) | catalogued as COSV52156289; called by muse, mutect2, varscan2
- ZNF714 | c.580G>T p.V194F | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.234); catalogued as COSV52514565; called by muse, mutect2, varscan2
- ZNF80 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100352185; called by muse, mutect2, varscan2
- ZP4 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.067); catalogued as rs368326237, COSV63911790; called by muse, mutect2, varscan2
- AADACL2 | c.128G>T p.C43F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, varscan2
- AASS | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 179/392 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ABCA3 | c.3074T>A p.V1025E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ABCA9 | c.4696C>A p.Q1566K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ABCC2 | c.2254G>C p.A752P | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ABCC8 | c.4112G>T p.G1371V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- AC011005.1 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ACTR10 | c.788+2T>A p.X263_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | called by muse, mutect2, varscan2
- ADAM19 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 97/167 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADAMTS10 | c.1637T>C p.V546A | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ADAMTS12 | c.355A>T p.M119L | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS14 | c.2078A>T p.E693V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1727G>T p.R576L | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2285G>T p.G762V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAT1 | c.306C>A p.H102Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADCYAP1 | c.389A>T p.K130M | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- ADGRA1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ADGRB1 | c.4502G>T p.R1501L | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- ADGRG7 | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- ADGRV1 | c.6787G>T p.G2263W | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA1D | c.981C>A p.H327Q | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ADRA2B | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2
- AFF3 | c.-63G>T | Splice Region (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- AGAP2 | c.2978G>T p.R993L (on ENST00000547588 / NM_001122772.2; = p.R637L on NM_014770.4) | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AGAP2 | c.1638G>T p.E546D (on ENST00000547588 / NM_001122772.2; = p.E210D on NM_014770.4) | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AGRN | c.4457G>T p.G1486V | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AGT | c.581A>T p.Q194L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- AHI1 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- AHNAK2 | c.14501C>A p.P4834Q | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AKAP9 | c.6035del p.K2012Rfs*4 (on ENST00000359028; = p.K1980Rfs*4 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel, varscan2
- AKR1B10 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); called by muse, mutect2
- ALDH1L2 | c.59A>G p.K20R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); called by mutect2, varscan2
- ALPI | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- AMER3 | c.1893G>T p.K631N | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- AMPD1 | c.1955C>A p.P652Q | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANAPC2 | c.1606G>T p.E536* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | called by mutect2, varscan2
- ANKRD18A | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- ANKRD18B | c.200A>T p.K67I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); called by muse, mutect2
- ANKRD26 | c.1954A>C p.S652R | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ANKRD30A | c.857C>T p.P286L (on ENST00000611781; = p.P230L on NM_052997.2) | Missense Mutation (SNP) | VAF 48/377 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANKRD30B | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD34A | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ANKRD34B | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ANKRD46 | c.352A>G p.R118G | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ANO7 | c.2390G>T p.R797L (on ENST00000274979; = p.R743L on NM_001370694.2) | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ANOS1 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- AOC2 | c.1705G>T p.D569Y | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- AP2A1 | c.1475G>T p.C492F | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- APBB1IP | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP22 | c.128G>T p.W43L | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ARHGAP4 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP44 | c.341del p.L114Cfs*3 | Frame Shift Del (DEL) | VAF 38/215 reads (18%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.904A>T p.S302C | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ARHGEF26 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.871C>A p.H291N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ARHGEF9 | c.1415A>T p.Q472L | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID3A | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ARID3C | c.94C>A p.L32M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARIH1 | c.14A>C p.E5A | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); called by muse, varscan2
- ASNSD1 | c.405G>T p.R135S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPH | c.2075G>C p.G692A | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ASPHD2 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASTN2 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.263); called by muse, varscan2
- ASXL3 | c.275G>A p.G92D | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10D | c.2482C>A p.Q828K | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ATP2B3 | c.2852T>A p.F951Y | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- ATP7A | c.2529A>T p.Q843H | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP7B | c.4397G>C p.*1466Sext*1 | Nonstop Mutation (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- ATP8A1 | c.2560A>T p.R854* | Nonsense Mutation (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1584+2T>A p.X528_splice | Splice Site (SNP) | VAF 49/99 reads (49%) | called by muse, mutect2, varscan2
- ATRNL1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- AVEN | c.1056G>C p.E352D | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- B3GALT1 | c.435T>G p.F145L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BBOX1 | c.629A>G p.H210R | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- BCL11B | c.452C>A p.P151Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BCL9 | c.1875A>T p.Q625H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- BICC1 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, varscan2
- BOD1L1 | c.5024A>T p.E1675V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BPIFB6 | c.1138del p.D380Tfs*4 | Frame Shift Del (DEL) | VAF 20/114 reads (18%) | called by mutect2, pindel*, varscan2
- BRINP3 | c.1739A>T p.H580L | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRIP1 | c.3220A>T p.I1074F | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- BRIP1 | c.944G>C p.G315A | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.1925C>A p.A642D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C1QTNF3 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C1orf146 | c.355C>A p.L119I | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.015); called by mutect2, varscan2
- C1orf94 | c.1679T>C p.M560T (on ENST00000488417 / NM_001134734.2; = p.M370T on NM_032884.5) | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C2CD2 | c.1272G>C p.K424N | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- C3orf20 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- C4orf54 | c.3265del p.V1089* | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | called by mutect2, pindel, varscan2
- C6 | c.2206T>A p.F736I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- C8orf33 | c.551-1G>T p.X184_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- C8orf48 | c.171G>T p.R57S | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAAP1 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA1C | c.4291T>A p.C1431S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNA1D | c.4844A>T p.Y1615F (on ENST00000350061 / NM_001128840.3; = p.Y1635F on NM_000720.4) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- CACNA1E | c.1337G>C p.S446T | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CACNA1E | c.2078C>A p.T693K | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CACNA1F | c.3512G>T p.R1171L | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- CAPN14 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPSL | c.257G>T p.R86M | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CASP5 | c.1046G>T p.C349F | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAT | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CATSPER1 | c.1170T>G p.H390Q | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBWD1 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CC2D1A | c.2076A>G p.E692= | Splice Region (SNP) | VAF 31/138 reads (22%) | called by muse, mutect2, varscan2
- CCDC178 | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CCDC39 | c.1229A>T p.Q410L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.234); called by muse, mutect2
- CCDC80 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CCDC91 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 31/289 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCR8 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCSER1 | c.2261G>T p.R754M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CD1B | c.969T>A p.Y323* | Nonsense Mutation (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- CD1C | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- CD248 | c.1691A>G p.Q564R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD248 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- CDC14C | c.737C>A p.A246D (on ENST00000428251; = p.A139D on NM_152627.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.361); called by mutect2, varscan2
- CDC42BPA | c.4549+1G>T p.X1517_splice (on ENST00000334218 / NM_001366019.2; = p.X1504_splice on NM_003607.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- CDCA5 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 72/142 reads (51%) | called by muse, varscan2
- CDH10 | c.1625-2A>T p.X542_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- CDH10 | c.814+1G>T p.X272_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- CDH11 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CDH12 | c.1298C>A p.T433K | Missense Mutation (SNP) | VAF 32/210 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CDH6 | c.250G>T p.G84* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- CDK18 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CDKL1 | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.596); called by muse, mutect2
- CDKL1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CENPF | c.6570_6571dup p.I2191Kfs*2 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | called by pindel, varscan2
- CEP85 | c.2162A>G p.Q721R | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CERS3 | c.474G>C p.W158C | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CES3 | c.1075C>G p.L359V | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CFAP44 | c.1460C>T p.T487I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- CFAP47 | c.8385G>T p.W2795C | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- CFAP54 | c.3916G>T p.D1306Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CFAP58 | c.2542T>A p.F848I | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFC1 | c.143A>T p.Q48L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by mutect2, varscan2
- CGB1 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- CHFR | c.1771+1G>T p.X591_splice (on ENST00000432561 / NM_001161345.1; = p.X550_splice on NM_018223.2) | Splice Site (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- CHIT1 | c.794C>A p.P265H | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CHN1 | c.59-1G>T p.X20_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | called by mutect2, varscan2
- CIAO2A | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA1 | c.50A>T p.E17V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CLCN1 | c.1829T>A p.V610E | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLCN1 | c.2115del p.E706Sfs*88 | Frame Shift Del (DEL) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- CLEC18A | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CLEC2L | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, varscan2
- CNBD1 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by mutect2, varscan2
- CNBD1 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CNTN5 | c.3233A>T p.H1078L | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CNTNAP2 | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, varscan2
- CNTNAP4 | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- CNTNAP5 | c.1153del p.Q385Kfs*7 | Frame Shift Del (DEL) | VAF 84/183 reads (46%) | called by mutect2, pindel, varscan2
- COL10A1 | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL17A1 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- COL1A2 | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 21/257 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A2 | c.3310-2A>T p.X1104_splice | Splice Site (SNP) | VAF 56/173 reads (32%) | called by muse, mutect2, varscan2
- COL6A3 | c.5387C>A p.A1796E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CORIN | c.455A>T p.Y152F | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COX7B2 | c.34A>T p.S12C | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CPN1 | c.1295G>T p.R432M | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- CPN1 | c.352A>T p.I118F | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- CPS1 | c.2923G>T p.G975* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- CPXM2 | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- CRABP1 | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRACR2A | c.529A>G p.S177G | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CRAMP1 | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.012); called by mutect2, varscan2
- CRB2 | c.706G>T p.A236S | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- CRNKL1 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- CROT | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CRYBG3 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- CRYGB | c.445C>A p.P149T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); called by muse, mutect2, varscan2
- CRYGD | c.259T>A p.S87T | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSF1 | c.950T>A p.V317E | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CSMD3 | c.7651G>T p.A2551S (on ENST00000297405 / NM_001363185.1; = p.A2447S on NM_052900.3) | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CSPP1 | c.479A>C p.K160T (on ENST00000676605; = p.K119T on NM_024790.6) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CTIF | c.1728C>A p.N576K | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CUX2 | c.1822C>A p.P608T | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWF19L1 | c.25T>A p.L9M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.520T>A p.C174S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CYP26B1 | c.557A>T p.Q186L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CYP2C19 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- CYP4F11 | c.175T>A p.W59R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP4F12 | c.24del p.W8Cfs*59 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel*, varscan2
- CYP7B1 | c.1464del p.L488Ffs*17 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- CYSLTR2 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DBX1 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- DCAF12L2 | c.89_90insA p.A31Gfs*88 | Frame Shift Ins (INS) | VAF 73/133 reads (55%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- DCT | c.507del p.N170Mfs*29 | Frame Shift Del (DEL) | VAF 47/163 reads (29%) | called by mutect2, pindel, varscan2
- DCTN4 | c.168A>T p.E56D | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDX10 | c.2167C>A p.H723N | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX50 | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- DEF6 | c.1693A>C p.S565R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.401); called by muse, varscan2
- DENND1B | c.1550G>C p.G517A | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DEPDC5 | c.1981A>G p.T661A (on ENST00000400246; = p.T730A on NM_014662.5) | Missense Mutation (SNP) | VAF 43/356 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- DERA | c.884C>G p.S295W | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- DERPC | c.1190C>A p.T397N | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- DGCR2 | c.844G>T p.G282W | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DHRS7C | c.838C>A p.P280T (on ENST00000330255 / NM_001220493.2; = p.P279T on NM_001105571.3) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by mutect2, varscan2
- DIDO1 | c.5332G>T p.A1778S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DIO2 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- DLG2 | c.1876G>C p.G626R | Missense Mutation (SNP) | VAF 53/203 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DLX1 | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- DMBT1 | c.6742T>A p.S2248T (on ENST00000338354 / NM_001377530.1; = p.S1491T on NM_004406.3) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- DMD | c.938C>A p.T313K | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- DNAH10 | c.8282C>T p.T2761I (on ENST00000409039; = p.T2700I on NM_207437.3) | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH5 | c.12902A>G p.Y4301C | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- DNAH5 | c.1525A>T p.T509S | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH7 | c.4466C>A p.S1489* | Nonsense Mutation (SNP) | VAF 66/247 reads (27%) | called by muse, mutect2, varscan2
- DNAH8 | c.4864G>T p.A1622S | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DNAH9 | c.3242T>A p.F1081Y | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH9 | c.4370C>G p.T1457S | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAI2 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DNAI2 | c.1257G>T p.R419S | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- DNAJB9 | c.71C>G p.S24* | Nonsense Mutation (SNP) | VAF 32/188 reads (17%) | called by muse, mutect2, varscan2
- DOCK2 | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DRAXIN | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DRG2 | c.806+1G>T p.X269_splice | Splice Site (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- DSG1 | c.2788dup p.T930Nfs*7 | Frame Shift Ins (INS) | VAF 100/195 reads (51%) | called by mutect2, pindel, varscan2
- DSP | c.3117G>T p.E1039D | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DSP | c.3118G>T p.E1040* | Nonsense Mutation (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- DSTYK | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- DTNA | c.635C>A p.T212K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- DYNC2H1 | c.7839G>T p.K2613N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ECEL1 | c.793C>A p.Q265K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- ECEL1 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- ECT2L | c.1328C>A p.A443D | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- EHMT1 | c.398A>T p.Q133L | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EHMT2 | c.2978G>C p.R993P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- EIF2D | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- EIF3B | c.1643G>A p.R548Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- EIF4E1B | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ELN | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ELN | c.1214C>G p.P405R | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ELP1 | c.2977G>T p.G993W | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EN1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.027); called by muse, mutect2
- ENPP2 | c.1427G>C p.G476A (on ENST00000075322 / NM_001040092.3; = p.G528A on NM_006209.5) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENPP6 | c.74A>T p.K25M | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ENTPD8 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- EP400 | c.9100G>T p.A3034S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- EPB41L5 | c.2030T>C p.L677P | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EPHA6 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- EPHA6 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EPHB1 | c.1367A>T p.Q456L | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- EPHB2 | c.1590A>G p.E530= | Splice Region (SNP) | VAF 45/360 reads (13%) | called by muse, mutect2, varscan2
- EPX | c.797T>A p.I266N | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ERAL1 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC2 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ERI1 | c.963A>T p.K321N | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ERICH2 | c.108G>T p.L36F | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ERICH4 | c.226G>T p.G76W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ERMARD | c.1679A>G p.Q560R | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERV3-1 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ERVMER34-1 | c.1261C>G p.R421G | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRRG | c.1224G>T p.M408I | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT2 | c.727G>T p.G243C (on ENST00000613624; = p.G167C on NM_020728.3) | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVC | c.348G>T p.K116N | Missense Mutation (SNP) | VAF 76/364 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, varscan2
- EXOC3 | c.1939-1G>T p.X647_splice | Splice Site (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2, varscan2
- EXTL2 | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 88/194 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- EZH1 | c.340dup p.W114Lfs*13 | Frame Shift Ins (INS) | VAF 29/130 reads (22%) | called by mutect2, pindel, varscan2
- FADS6 | c.412-3T>C | Splice Region (SNP) | VAF 85/198 reads (43%) | called by muse, mutect2, varscan2
- FAM13C | c.1490A>T p.K497I | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- FAM155B | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FAM180A | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM234B | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- FAM47B | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- FAM47C | c.2411C>G p.P804R | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- FAM50A | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 29/175 reads (17%) | called by muse, mutect2, varscan2
- FAM83B | c.1971G>T p.E657D | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAP | c.892T>A p.W298R | Missense Mutation (SNP) | VAF 58/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAT3 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- FAT3 | c.7470C>A p.N2490K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.9600C>A p.D3200E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO34 | c.820A>T p.S274C | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- FBXO38 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- FBXW9 | c.443A>T p.E148V (on ENST00000587955; = p.E158V on NM_032301.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- FCGR2A | c.499C>A p.H167N (on ENST00000271450 / NM_001136219.3; = p.H166N on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/448 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FCRL1 | c.207del p.K70Sfs*27 | Frame Shift Del (DEL) | VAF 58/204 reads (28%) | called by mutect2, pindel, varscan2
- FCRL3 | c.1580G>T p.G527V | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCRL5 | c.686T>A p.F229Y | Missense Mutation (SNP) | VAF 55/326 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FER1L5 | c.141C>A p.T47= | Splice Region (SNP) | VAF 46/177 reads (26%) | called by muse, mutect2, varscan2
- FER1L5 | c.1253-1G>T p.X418_splice (on ENST00000623019; = p.X423_splice on NM_001293083.2) | Splice Site (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- FEZF1 | c.936+1G>T p.X312_splice | Splice Site (SNP) | VAF 42/149 reads (28%) | called by muse, mutect2, varscan2
- FGD5 | c.1082G>T p.S361I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FGD5 | c.1938C>A p.Y646* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- FGF14 | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FLG | c.3971A>G p.D1324G | Missense Mutation (SNP) | VAF 97/269 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- FLG | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FLG2 | c.6278G>T p.R2093I | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FLG2 | c.2321G>T p.S774I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FLG2 | c.1046C>A p.S349Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLNC | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMN2 | c.598C>A p.Q200K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- FMN2 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- FOCAD | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 46/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXO3 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FOXP1 | c.1666A>G p.I556V | Missense Mutation (SNP) | VAF 212/464 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRMD1 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FRMD8 | c.658G>C p.G220R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FRMPD4 | c.3905C>A p.P1302H | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSCB | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, mutect2, varscan2
1,302 further variants in this file (697 protein-altering or splice-affecting, 395 silent, 210 other) are not listed here.
